Surgical pathology report (de-identified scan), TCGA case TCGA-WB-A817, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Erasmus MC, specimen TCGA-WB-A817-01A (Primary Tumor).

Left and right adrenalectomy

Date receiving:

Clinical history Hypertension recently revealed by sudden headaches. No risk factors. Investigations showed bilateral adrenal nodules attributed to pheochromocytomas by metanephrine measurements.

Macroscopy

Left Adrenal: The surgical specimen weights 14g after dissection of fat and measures 6.5 x 2.5 x 2.5 cm. After cutting, a grayish nodule is observed in adrenal measuring 1 cm.

Right adrenal. After fat dissection, the surgical piece weights 23 g and measures 6.5 x 4 x 4 cm, with after cutting, a intra-adrenal grayish beige tumor measuring 2cm.

Microscopy

Left Adrenal: a proliferation organized into bays or small nests within a sparse interstitial vascularized tissue with very small hemorrhagic areas is observed. The tumor cells are large. Cytoplasm are polygonal basophils. Nuclei exhibit a slight degree of anisokaryosis with a small nucleolus sufficiently visible. Absence of mitosis. Absence of necrosis.

The tumor is limited by a fibrous condensation sometimes clear and sometimes less clear separating the tumor from the rest of the adrenal tissue and the adipose tissue. Presence of cell clusters floating in the blood vessels. Absence of capsular infiltration and absence of tumor embolus. The outside adrenal is normal.

PASS score: large nests or diffuse architecture: 0. Central or confluent necrosis: 0. High cellularity: 0. Cellular monotony: 0. Tumor cell spindling: 0. Mitotic figures: 0. Vascular invasion: 0. Capsular invasion: 0. Profound nuclear pleomorphism: 0. Nuclear hyperchromasia: 0 ..

IHC study showed that the tumor cells express chromogranin, synaptophysin and N Cam.

CONCLUSION

Benign pheochromocytoma, 1 cm.

PASS Score = 0 ..

Right Adrenal: Benign pheochromocytoma measuring 2 cm

PASS Score = 0.

Cytological and immunohistochemical morphological characteristics are identical to those described above for the left tumor

Translated on from the original pathological report evaluated on

ICD-O-3
Pheochromocytoma NOS 8700/0
Site: (R) Adrenal gland NOS C74.9
JW 10/17/13

Trisomy History		
Idiopathic Primary Noted		
Case is Telepath		

Source: NCI Genomic Data Commons file d292b1cc-1aff-4be3-9fd6-8907d6874d45 (TCGA-WB-A817.1FD8E6AA-93F6-474A-877A-3606E268B038.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).